TCGA case TCGA-G4-6303 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/264c0d45-078a-4207-a101-71f99bcd237e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Dead; Days to death: 2,003 days (5.5 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,800 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 25; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 516 days (1.4 years); Days to treatment end: 682 days (1.9 years); Number of cycles: 6; Treatment dose: 3,960 mg; Prescribed dose: 660; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 516 days (1.4 years); Days to treatment end: 682 days (1.9 years); Number of cycles: 6; Treatment dose: 990 mg; Prescribed dose: 165; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Fluorouracil + Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 896 days (2.5 years); Days to treatment end: 1,443 days (4.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 1,443 days (4.0 years); Days to treatment end: 1,596 days (4.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab + Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,596 days (4.4 years); Days to treatment end: 1,838 days (5.0 years); Number of cycles: 12.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 1,840 days (5.0 years); Days to treatment end: 1,994 days (5.5 years); Number of cycles: 10; Treatment dose: 3,240 mg; Prescribed dose: 325; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 1,840 days (5.0 years); Days to treatment end: 1,994 days (5.5 years); Number of cycles: 10; Treatment dose: 6,790 mg; Prescribed dose: 680; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,840 days (5.0 years); Days to treatment end: 1,994 days (5.5 years); Number of cycles: 10; Treatment dose: 1,450 mg; Prescribed dose: 145; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.6 years (20,672 days); Days to diagnosis: 872 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 872 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 872 days (2.4 years).
- Days to follow up: 1,882 days (5.2 years); Disease response: With Tumor.
- Days to follow up: 2,003 days (5.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 3.8 ng/mL.
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 69 kg.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6303-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-G4-6303-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-G4-6303-01A-01-TS1: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 25.
- Sample TCGA-G4-6303-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6303-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Weight kg at diagnosis: 69 kg; Lymph nodes examined: Yes; CEA level pretreatment: 3.8; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; KRAS mutation found: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: 5-FU; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: 5-FU; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 5; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 9: Regimen number: 5; Pharmaceutical therapy drug name: 5-FU; Therapy regimen: Progression.
- Drug treatment 10: Regimen number: 2; Pharmaceutical therapy drug name: 5-FU; Therapy regimen: Progression.
- Drug treatment 13: Regimen number: 4; Pharmaceutical therapy drug name: Erbitux; Therapy regimen: Progression.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,003 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,003 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 872 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G4-6303-01A-11D-1770-01): tumor purity 0.68, ploidy 3.33, whole-genome doublings 1.
